Somatic mutation profile of tumor specimen TCGA-42-2589-01A (aliquot TCGA-42-2589-01A-01D-1526-09) from TCGA case TCGA-42-2589, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.4 years (19,852 days).
Specimen TCGA-42-2589-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d55cbad-61be-4c07-8fec-854eb6d2cac4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-42-2589-10A (Blood Derived Normal), aliquot TCGA-42-2589-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad7ca70c-3c68-4233-a5f9-026deb1e5634

The open-access MAF lists 102 somatic variants for this specimen: 83 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 17, Splice Site 3, Nonsense Mutation 3, In Frame Del 2, RNA 2, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs781943956, CM123978, COSV100811788; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 59/83 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs373224846, COSV100069002; called by muse, mutect2, varscan2
- ACVRL1 | c.340G>T p.G114* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as COSV66361040; called by muse, mutect2, varscan2
- AKNAD1 | c.1786G>C p.E596Q | Missense Mutation (SNP) | VAF 21/658 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100645792; called by muse, mutect2
- APOB | c.9667T>C p.Y3223H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1324189615, COSV51922814; called by muse, mutect2
- AQP12B | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV68184458; called by muse, mutect2, varscan2
- AXIN2 | c.278A>T p.Y93F | Missense Mutation (SNP) | VAF 174/217 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV61060894; called by muse, mutect2, varscan2
- B3GALNT2 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 310/402 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs373773440; called by muse, mutect2, varscan2
- BIRC6 | c.3488A>C p.E1163A | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV70205509; called by muse, mutect2, varscan2
- C11orf42 | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV56414612; called by muse, mutect2, varscan2
- CAMK2B | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99323397; called by muse, mutect2
- CDH18 | c.1859T>A p.L620H | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56958908; called by muse, mutect2, varscan2
- CEACAM8 | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 148/208 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as COSV54991738, COSV99747387; called by muse, mutect2, varscan2
- COG8 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 70/102 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs778596903, COSV55340356; called by muse, mutect2, varscan2
- COL3A1 | c.2391+1G>A p.X797_splice | Splice Site (SNP) | VAF 26/73 reads (36%) | catalogued as COSV58596102; called by muse, mutect2, varscan2
- CPLX4 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV55312766; called by muse, mutect2, varscan2
- CYP4Z1 | c.1435C>A p.H479N | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV61966578; called by muse, mutect2, varscan2
- DCHS1 | c.8143G>A p.V2715M | Missense Mutation (SNP) | VAF 107/148 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs757739092, COSV54998038, COSV54998995; called by muse, mutect2, varscan2
- DCTN1 | c.1718T>C p.L573S | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62621456; called by muse, mutect2, varscan2
- DGKI | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV55974335; called by muse, mutect2, varscan2
- DHX29 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52421987; called by muse, mutect2, varscan2
- DNAH3 | c.7621G>A p.V2541I | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1397174952, COSV54549763; called by muse, mutect2, varscan2
- ELF4 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100257554; called by muse, mutect2
- EMILIN1 | c.1078C>G p.R360G | Missense Mutation (SNP) | VAF 60/76 reads (79%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV53157197; called by muse, mutect2, varscan2
- ERCC6L | c.884C>G p.T295S | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV57822308; called by muse, mutect2
- FAM13A | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 46/65 reads (71%) | catalogued as rs1446021359, COSV52012790; called by muse, mutect2, varscan2
- FLRT1 | c.1681G>C p.V561L | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV55367188; called by muse, mutect2, varscan2
- FOXO3 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV59631149; called by mutect2, varscan2
- FRMD6 | c.1208C>T p.P403L (on ENST00000344768 / NM_001267046.2; = p.P395L on NM_152330.4) | Missense Mutation (SNP) | VAF 141/195 reads (72%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1313057241, COSV61090689; called by muse, mutect2, varscan2
- FRMPD4 | c.3797C>A p.P1266H | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.117); catalogued as COSV66222937; called by muse, mutect2, varscan2
- GAL3ST3 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.341); catalogued as COSV100360965; called by muse, mutect2
- GPR182 | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV55627108; called by muse, mutect2, varscan2
- IFNA14 | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 89/284 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.074); catalogued as COSV66516448; called by muse, varscan2
- KCNH1 | c.481A>T p.S161C | Missense Mutation (SNP) | VAF 111/454 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55101219; called by muse, mutect2, varscan2
- KCNH4 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52920726; called by muse, mutect2, varscan2
- KIFC1 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV65737894; called by muse, mutect2, varscan2
- KMT2E | c.2938G>C p.G980R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV57579411; called by muse, varscan2
- KPRP | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 72/417 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.048); catalogued as COSV64222948; called by muse, mutect2, varscan2
- LAMC1 | c.4505A>G p.N1502S | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV51175202; called by muse, mutect2, varscan2
- LRATD2 | c.590G>C p.S197T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.721); catalogued as rs1467372168, COSV59230699; called by muse, mutect2, varscan2
- MATN4 | c.1643C>T p.A548V (on ENST00000372754; = p.A507V on NM_003833.4) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | PolyPhen benign (0.217); catalogued as COSV61352966; called by muse, mutect2, varscan2
- MCM3 | c.801G>A p.R267= (on ENST00000229854 / NM_001366374.2; = p.R257= on NM_002388.6 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 52/128 reads (41%) | catalogued as COSV57719352; called by muse, mutect2, varscan2
- MCM6 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV51469230; called by muse, mutect2, varscan2
- MCMBP | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100750152; called by muse, mutect2
- MPP7 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV100517776; called by muse, mutect2, varscan2
- NOS3 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.169); catalogued as COSV52495430; called by muse, mutect2, varscan2
- NTRK1 | c.1880T>G p.L627R | Missense Mutation (SNP) | VAF 88/159 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100693699; called by muse, mutect2
- NUP43 | c.346A>C p.T116P | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100462250; called by muse, mutect2
- OR8A1 | c.855T>A p.N285K | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV52510327; called by muse, mutect2, varscan2
- ORC2 | c.1051-1G>T p.X351_splice | Splice Site (SNP) | VAF 46/139 reads (33%) | catalogued as COSV52241468; called by muse, mutect2, varscan2
- PCCA | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66198470; called by muse, mutect2, varscan2
- PLAG1 | c.1477C>A p.P493T | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100388160; called by muse, mutect2, varscan2
- POLN | c.2431G>T p.D811Y | Missense Mutation (SNP) | VAF 153/721 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV67027566; called by muse, mutect2, varscan2
- PORCN | c.1216G>A p.A406T (on ENST00000326194 / NM_203475.3; = p.A395T on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 196/468 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs781834255, COSV52142260; called by muse, mutect2, varscan2
- PTK2B | c.18G>T p.E6D | Missense Mutation (SNP) | VAF 193/258 reads (75%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV57765637; called by muse, mutect2
- PTPDC1 | c.255-1G>A p.X85_splice (on ENST00000375360 / NM_177995.3; = p.X137_splice on NM_152422.4) | Splice Site (SNP) | VAF 28/342 reads (8%) | catalogued as COSV56626512; called by muse, mutect2
- PTPRR | c.1374G>C p.K458N | Missense Mutation (SNP) | VAF 129/352 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV51747150; called by muse, mutect2, varscan2
- REXO5 | c.1144C>G p.H382D | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54474626; called by mutect2, varscan2
- RTN4IP1 | c.1112C>G p.P371R | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV100954079, COSV64806421; called by muse, mutect2, varscan2
- SETD1A | c.4245C>G p.Y1415* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV52692202; called by muse, varscan2
- SIGLEC1 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 201/880 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV52472037; called by muse, mutect2, varscan2
- SLAMF6 | c.625T>C p.S209P | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63588166; called by muse, mutect2, varscan2
- SLC9A7 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100092638; called by muse, mutect2
- SMIM29 | c.239T>G p.V80G (on ENST00000394990 / NM_001008704.3; = p.V100G on NM_178508.5) | Missense Mutation (SNP) | VAF 83/151 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.266); catalogued as COSV58988931; called by muse, mutect2, varscan2
- SNX17 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 277/630 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV52009361, COSV52010313; called by muse, mutect2, varscan2
- SNX29 | c.891C>A p.D297E | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.891); catalogued as rs767539574, COSV60070115; called by muse, mutect2, varscan2
- SOX6 | c.1539G>T p.E513D (on ENST00000528429 / NM_001145819.2; = p.E486D on NM_017508.3) | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV57057650; called by muse, mutect2, varscan2
- SPRYD3 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 149/368 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs1053920436, COSV100036861; called by muse, mutect2, varscan2
- SPRYD3 | c.747G>C p.Q249H | Missense Mutation (SNP) | VAF 153/370 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100036862; called by muse, mutect2, varscan2
- THRAP3 | c.1131C>A p.S377R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100663544; called by muse, mutect2
- TINAG | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52514729; called by muse, mutect2, varscan2
- TSPEAR | c.607C>G p.R203G | Missense Mutation (SNP) | VAF 170/368 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs199858107, COSV59978987; called by muse, mutect2, varscan2
- UBASH3B | c.1538C>A p.A513E | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.315); catalogued as COSV52502165; called by muse, mutect2, varscan2
- VIRMA | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV52591012; called by muse, mutect2, varscan2
- ZMYM3 | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.011); catalogued as COSV58740670, COSV58740746; called by muse, mutect2, varscan2
- ZZEF1 | c.7643C>A p.S2548Y | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV67560161; called by muse, mutect2, varscan2
- CBWD6 | c.1081G>C p.G361R | Missense Mutation (SNP) | VAF 238/344 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC42BPA | c.2703_2711del p.N901_V903del | In Frame Del (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.2773_2799del p.L926_L934del | In Frame Del (DEL) | VAF 24/222 reads (11%) | called by mutect2, pindel
- PCGF2 | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIF1 | c.6897_6905dup p.A2300_V2302dup | In Frame Ins (INS) | VAF 58/154 reads (38%) | called by mutect2, varscan2
- UGT2B4 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- A1CF | c.1221G>T p.L407= (on ENST00000373993 / NM_138932.2; = p.L399= on NM_014576.4) | Silent (SNP) | VAF 89/232 reads (38%) | catalogued as COSV51018745; called by muse, mutect2, varscan2
- ADGRG3 | c.480G>T p.G160= | Silent (SNP) | VAF 138/194 reads (71%) | catalogued as COSV59650989; called by muse, mutect2, varscan2
- ALDH1L1 | c.141G>A p.E47= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV56419053; called by muse, mutect2, varscan2
- ARHGAP24 | c.960G>A p.V320= (on ENST00000395184 / NM_001025616.3; = p.V227= on NM_031305.3) | Silent (SNP) | VAF 82/123 reads (67%) | catalogued as COSV51993366; called by muse, mutect2, varscan2
- CLK1 | c.528G>C p.V176= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV58435784; called by muse, mutect2, varscan2
- CNPY4 | c.390G>C p.G130= | Silent (SNP) | VAF 32/750 reads (4%) | catalogued as COSV99498900; called by muse, mutect2
- DMRT3 | c.1089C>A p.P363= | Silent (SNP) | VAF 91/121 reads (75%) | catalogued as COSV51908613; called by muse, mutect2, varscan2
- GAS8 | c.1350C>T p.D450= | Silent (SNP) | VAF 238/284 reads (84%) | catalogued as COSV51945981; called by muse, mutect2, varscan2
- HCN1 | c.2391G>A p.V797= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV100299842, COSV57507087; called by muse, mutect2, varscan2
- LCE2A | c.171G>T p.G57= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs61812671, COSV100909212, COSV64227066; called by muse, mutect2, varscan2
- LRRC10 | c.627G>A p.A209= | Silent (SNP) | VAF 25/296 reads (8%) | catalogued as rs770103230, COSV100825516; called by muse, mutect2
- LYSMD1 | c.405T>A p.G135= | Silent (SNP) | VAF 119/948 reads (13%) | catalogued as COSV64420404; called by muse, mutect2, varscan2
- MYRIP | c.1414C>T p.L472= | Silent (SNP) | VAF 55/302 reads (18%) | catalogued as COSV56880925; called by muse, mutect2, varscan2
- NEMP1 | c.18A>G p.K6= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV55664559; called by muse, mutect2, varscan2
- PACSIN2 | c.636G>T p.L212= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99606591; called by muse, mutect2, varscan2
- PCK1 | c.807T>A p.G269= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as COSV60131032; called by muse, mutect2, varscan2
- PLAG1 | c.1476C>A p.L492= | Silent (SNP) | VAF 56/275 reads (20%) | catalogued as COSV100388161; called by muse, mutect2, varscan2
- AL590867.2 | n.38G>T | RNA (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- BIRC8 | n.1395C>G | RNA (SNP) | VAF 39/182 reads (21%) | catalogued as COSV70347914; called by muse, mutect2, varscan2
